Somatic mutation profile of tumor specimen ALCH-B2LY-TTP1-A (aliquot ALCH-B2LY-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2LY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 56.4 years (20,586 days).
Specimen ALCH-B2LY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b16054e-a3a9-442a-a482-46b0864ae0ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2LY-NB1-A (Blood Derived Normal), aliquot ALCH-B2LY-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49dca204-9ff8-4a99-85bb-bd1250fc1b0b

The open-access MAF lists 253 somatic variants for this specimen: 176 protein-altering or splice-affecting, 49 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 49, Intron 16, Nonsense Mutation 11, RNA 5, Frame Shift Ins 5, Frame Shift Del 4, 3'UTR 3, Splice Region 2, 5'Flank 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 70/315 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7522T>A p.F2508I (on ENST00000272895 / NM_173076.3; = p.F2190I on NM_015657.3) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99788156; called by muse, mutect2, varscan2
- ADAM8 | c.1916A>G p.H639R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1276033505; called by muse, mutect2, varscan2
- AKAP11 | c.1203C>G p.F401L | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50292758; called by muse, mutect2
- ANGPTL6 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1309257997; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4254C>A p.D1418E | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); catalogued as COSV99784604; called by muse, mutect2
- ANTKMT | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV53495621; called by muse, mutect2
- ARID1A | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 73/236 reads (31%) | catalogued as COSV61378997; called by muse, mutect2, varscan2
- CBX1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99847954; called by muse, mutect2
- CDH8 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54859312, COSV54862714, COSV54871576; called by muse, mutect2, varscan2
- CRTAM | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs759987502, COSV99911812; called by muse, mutect2, varscan2
- DDX21 | c.1177A>G p.T393A | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs183544044; called by muse, mutect2, varscan2
- DEUP1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as COSV53215778; called by muse, mutect2
- DOCK10 | c.5971G>A p.G1991S | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369050199, COSV51346695; called by muse, mutect2, varscan2
- DSCAM | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs374471813; called by muse, mutect2, varscan2
- DUSP8 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as rs778215704; called by muse, mutect2, varscan2
- FAM155A | c.694T>C p.W232R | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs753098474; called by muse, mutect2, varscan2
- FAM90A1 | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1324066864; called by muse, mutect2, varscan2
- FREM1 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774222538; called by muse, mutect2, varscan2
- FZD9 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV60669769; called by muse, mutect2, varscan2
- GRIN2A | c.2146G>T p.A716S | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM138252, COSV58032355, COSV58060561; called by muse, mutect2, varscan2
- HCN1 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV57509556; called by muse, mutect2, varscan2
- KCNQ5 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 50/389 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.015); catalogued as rs1427601429; called by muse, mutect2, varscan2
- KCNT2 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.168); catalogued as COSV54091974; called by muse, mutect2, varscan2
- LCOR | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs1252580231, COSV63629918; called by muse, mutect2
- LDAH | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as rs751055188; called by muse, mutect2, varscan2
- MADD | c.4208C>G p.S1403W | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100212037; called by muse, mutect2, varscan2
- MAN2B1 | c.1026+8C>T | Splice Region (SNP) | VAF 48/136 reads (35%) | catalogued as rs199908179; ClinVar: uncertain significance; called by muse, mutect2
- MEPCE | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52769435, COSV52770376; called by muse, mutect2
- MKI67 | c.6917C>A p.P2306H | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV100896215; called by muse, mutect2, varscan2
- NDN | c.309C>G p.H103Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV59358217; called by muse, mutect2, varscan2
- NFATC2 | c.1626del p.R543Dfs*54 | Frame Shift Del (DEL) | VAF 19/156 reads (12%) | catalogued as COSV65352879; called by mutect2, pindel, varscan2
- OR4A5 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs142357039; called by muse, mutect2, varscan2
- OR6K6 | c.962A>G p.N321S (on ENST00000368144; = p.N297S on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63743765; called by muse, mutect2
- OR6X1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV60009585; called by muse, mutect2, varscan2
- PCLO | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61618047; called by muse, mutect2
- PKP3 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1444267910; called by muse, mutect2, varscan2
- PROSER1 | c.2353A>G p.N785D | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs771669084; called by muse, mutect2, varscan2
- PYGL | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs746639258; called by muse, mutect2, varscan2
- PYROXD2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100995960; called by muse, mutect2
- RNF141 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs1355631974; called by muse, mutect2
- SBF1 | c.1967G>T p.R656L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs778794053, COSV62365106; called by muse, mutect2, varscan2
- SPTBN2 | c.3335G>A p.G1112E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1219412799; called by muse, mutect2, varscan2
- STMND1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs1406868352, COSV100588361; called by muse, mutect2, varscan2
- THBS4 | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63470739; called by muse, mutect2, varscan2
- TIGD5 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1211583093, COSV57817610; called by muse, mutect2
- TJP2 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1411553268; called by muse, mutect2
- TLX3 | c.797C>G p.S266W | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51539472; called by muse, mutect2, varscan2
- TP53 | c.225dup p.A76Cfs*73 | Frame Shift Ins (INS) | VAF 30/87 reads (34%) | catalogued as COSV53671373; called by mutect2, pindel, varscan2
- TRIM58 | c.165C>A p.Y55* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs1270120887, COSV63570009; called by muse, mutect2, varscan2
- TRMT1 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs757496131, COSV99456872; called by muse, mutect2, varscan2
- TRPC5 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779139729, COSV53290819, COSV53293084; called by muse, mutect2, varscan2
- UBQLN3 | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.13); catalogued as COSV100294005, COSV61164323; called by muse, mutect2, varscan2
- VPS13A | c.7228G>A p.G2410R | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62442087; called by muse, mutect2, varscan2
- VPS35L | c.2337C>A p.F779L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs912534064, COSV99221964; called by muse, mutect2, varscan2
- VWA5B1 | c.2977C>T p.R993C (on ENST00000375079; = p.R988C on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as rs375681162; called by muse, mutect2, varscan2
- ZNF536 | c.3445A>T p.I1149F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); catalogued as rs1020625212; called by muse, mutect2, varscan2
- AADACL2 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AC011455.2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.3210C>A p.S1070R | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ADGB | c.3296C>A p.P1099Q | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- AKAP9 | c.6359A>G p.Q2120R (on ENST00000359028; = p.Q2088R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ALG6 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMELX | c.17T>C p.L6S | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ANK1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ANTXR2 | c.1337C>A p.T446N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP000721.1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBEC3B | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.333); called by muse, mutect2
- ASXL3 | c.5037dup p.R1680* | Frame Shift Ins (INS) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- C6 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CACNA1I | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, varscan2
- CASD1 | c.877A>T p.K293* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | called by muse, varscan2
- CCT2 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEMIP2 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2
- CEP120 | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CEP170B | c.1399T>G p.S467A (on ENST00000453495; = p.S396A on NM_015005.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CFAP126 | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.076); called by muse, mutect2
- CMSS1 | c.780del p.L261Wfs*14 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | called by mutect2, pindel, varscan2
- CNTN4 | c.1583A>G p.D528G | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2
- COL6A5 | c.7720C>G p.L2574V (on ENST00000312481; = p.L2570V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.038); called by muse, mutect2
- CSMD3 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CTLA4 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DAPK2 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DCAF10 | c.947C>A p.S316* | Nonsense Mutation (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- DENND2C | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DGKZ | c.2569G>C p.E857Q (on ENST00000454345 / NM_001105540.2; = p.E669Q on NM_003646.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DLGAP4 | c.1137C>A p.D379E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECHDC1 | c.187G>A p.G63S (on ENST00000531967 / NM_001139510.1; = p.G57S on NM_018479.3) | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENPP5 | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ETV5 | c.35dup p.M12Ifs*9 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | called by mutect2, varscan2
- ETV5 | c.33dup p.M12Yfs*9 | Frame Shift Ins (INS) | VAF 18/134 reads (13%) | called by mutect2*, pindel, varscan2*
- EVA1A | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- FAM124A | c.795G>T p.W265C (on ENST00000322475 / NM_001242312.2; = p.W301C on NM_145019.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- FBXL4 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FLT4 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GNPDA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPR135 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GRIN2A | c.1859A>G p.Q620R | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HOXD10 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- INTS4 | c.1933A>G p.R645G | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ITGA4 | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KCNN3 | c.1276A>T p.S426C | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KIAA1671 | c.2135A>G p.N712S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP10-2 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- LECT2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 58/202 reads (29%) | called by muse, mutect2, varscan2
- MALRD1 | c.5308G>A p.D1770N | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MAN1A1 | c.757A>T p.M253L | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- MGA | c.2012A>T p.K671M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MNDA | c.1202A>G p.E401G | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MPL | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MYH11 | c.3476T>A p.L1159Q | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NACC2 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NCAPG2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 7/197 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- NT5DC3 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR10P1 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- OR2AK2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR4C16 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR4K2 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OR52J3 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR5B17 | c.786del p.S263Vfs*16 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- OR5M11 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR7D4 | c.577del p.L193Sfs*19 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.4887T>A p.L1629= | Splice Region (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- PARP14 | c.4934T>C p.I1645T | Missense Mutation (SNP) | VAF 126/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM1 | c.2959C>G p.H987D | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRB1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PRKRA | c.276_277insT p.E93* | Frame Shift Ins (INS) | VAF 54/420 reads (13%) | called by mutect2, pindel*, varscan2*
- PRSS1 | c.533A>T p.K178M | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2
- PTBP2 | c.300A>T p.K100N (on ENST00000426398 / NM_001300986.2; = p.K92N on NM_021190.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- RAPGEF6 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2, varscan2
- RASGEF1A | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASSF3 | c.618C>A p.D206E | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RERE | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RFX8 | c.781C>T p.R261* (on ENST00000646446; = p.R190* on NM_001145664.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- RNF121 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- ROBO4 | c.2032T>C p.S678P | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RPTN | c.1691G>A p.R564K | Missense Mutation (SNP) | VAF 19/578 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.37); called by muse, mutect2
- SAT2 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN3A | c.3384A>C p.E1128D | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.06); called by muse, mutect2
- SFRP1 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by mutect2, varscan2
- SLC30A8 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, varscan2
- SPAM1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SPTBN4 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ST14 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- STAG2 | c.124-2A>G p.X42_splice | Splice Site (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- STAM | c.1520A>G p.Q507R | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, varscan2
- STIM2 | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2
- SUSD4 | c.440G>C p.C147S | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2
- TAF1L | c.4904A>T p.K1635M | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- TFAP2A | c.1025C>G p.A342G (on ENST00000482890; = p.A334G on NM_001032280.3) | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- THSD7A | c.2549T>A p.V850E | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TIAM2 | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- TLN1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TMEM128 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- TMEM131 | c.4082A>T p.H1361L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM237 | c.515T>C p.I172T (on ENST00000409883 / NM_001044385.3; = p.I164T on NM_152388.4) | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM87B | c.1614C>G p.I538M | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- TMTC3 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- TNN | c.2722G>T p.V908F | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPP1 | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- TUBD1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- TUT7 | c.1379A>T p.Y460F | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- U2SURP | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- UBQLNL | c.721A>T p.I241F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC80 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- UPF1 | c.1618C>G p.Q540E (on ENST00000599848 / NM_001297549.2; = p.Q529E on NM_002911.4) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- USF3 | c.2978T>A p.M993K | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2
- UTP20 | c.4645A>G p.I1549V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- XIRP2 | c.457G>C p.E153Q (on ENST00000628543; = p.E328Q on NM_152381.6) | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZBTB5 | c.302T>G p.L101W | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF347 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- ZNF816-ZNF321P | c.273A>T p.Q91H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ZSCAN12 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.048); called by muse, mutect2
- ABCA8 | c.1965C>T p.C655= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs781158837, COSV52194068; called by muse, mutect2, varscan2
- ABCC5 | c.762C>T p.I254= | Silent (SNP) | VAF 151/412 reads (37%) | catalogued as rs766500883, COSV55592910; called by muse, mutect2, varscan2
- ADCY10 | c.267T>C p.F89= | Silent (SNP) | VAF 87/354 reads (25%) | called by muse, mutect2, varscan2
- ANKRD24 | c.903C>T p.A301= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- ARSH | c.243T>C p.R81= | Silent (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- CACNA1A | c.477C>T p.F159= | Silent (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- CARMIL2 | c.603C>A p.L201= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- CCDC182 | c.363C>T p.R121= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV54989072; called by muse, mutect2, varscan2
- DHX8 | c.2682A>T p.T894= | Silent (SNP) | VAF 20/78 reads (26%) | called by mutect2, varscan2
- DNAH11 | c.11583G>A p.E3861= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- DOK5 | c.27G>A p.V9= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as rs1397678070; called by muse, varscan2
- EGFLAM | c.264G>A p.V88= | Silent (SNP) | VAF 77/216 reads (36%) | catalogued as COSV59317277; called by muse, mutect2, varscan2
- FAT2 | c.3741C>T p.F1247= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as COSV99941764; called by muse, mutect2, varscan2
- FOS | c.45C>A p.S15= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs1389165811; called by muse, mutect2, varscan2
- GALC | c.1380A>G p.E460= | Silent (SNP) | VAF 34/194 reads (18%) | catalogued as rs1370652050; called by muse, mutect2, varscan2
- GLI2 | c.363C>T p.Y121= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs748827715, COSV58034395; called by muse, mutect2, varscan2
- ITGA6 | c.2079T>C p.Y693= (on ENST00000442250; = p.Y654= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/248 reads (20%) | catalogued as rs890179235; called by muse, mutect2, varscan2
- ITGB4 | c.1413C>T p.N471= | Silent (SNP) | VAF 94/304 reads (31%) | catalogued as rs375790655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCN1 | c.192G>T p.G64= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- LRP1B | c.9777A>G p.T3259= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- MC2R | c.831C>T p.A277= | Silent (SNP) | VAF 12/181 reads (7%) | catalogued as rs754718068; called by muse, mutect2
- MKRN3 | c.396T>G p.V132= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- MOGAT3 | c.603C>A p.V201= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV56173286; called by muse, mutect2, varscan2
- MROH2B | c.801C>A p.G267= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- MTUS2 | c.648A>T p.P216= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs1475725192; called by muse, mutect2, varscan2
- MUC16 | c.195C>T p.A65= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- MYRFL | c.1236A>T p.G412= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- NCLN | c.741G>T p.V247= | Silent (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- NEB | c.7309C>A p.R2437= | Silent (SNP) | VAF 65/311 reads (21%) | catalogued as CM164918; called by muse, mutect2, varscan2
- OGDHL | c.1182G>T p.L394= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1259547791; called by muse, mutect2, varscan2
- OR2T2 | c.822G>C p.V274= | Silent (SNP) | VAF 32/420 reads (8%) | catalogued as COSV61618388; called by muse, varscan2
- PI4K2A | c.405C>T p.S135= | Silent (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- PROKR1 | c.1080C>T p.H360= | Silent (SNP) | VAF 86/270 reads (32%) | called by muse, mutect2, varscan2
- PTPRC | c.3432C>G p.V1144= | Silent (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- RANBP17 | c.1377T>C p.L459= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- RIPPLY1 | c.354A>G p.L118= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- SCN4A | c.1944C>T p.I648= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- SDK2 | c.126C>T p.N42= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs755561715, COSV66183834; called by muse, mutect2, varscan2
- SNX13 | c.1053G>A p.L351= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- SPATA31A6 | c.1545G>A p.K515= | Silent (SNP) | VAF 60/381 reads (16%) | called by muse, mutect2, varscan2
- TAS2R46 | c.150T>A p.A50= | Silent (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2, varscan2
- TMEM130 | c.477C>T p.V159= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- TNNT1 | c.159A>G p.P53= | Silent (SNP) | VAF 52/185 reads (28%) | called by muse, mutect2, varscan2
- TRIM51 | c.909T>C p.C303= | Silent (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- UBXN6 | c.1164C>G p.S388= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs139535362; called by muse, mutect2, varscan2
- ZBTB38 | c.1329T>A p.T443= | Silent (SNP) | VAF 33/337 reads (10%) | called by muse, mutect2, varscan2
- ZNF257 | c.1164T>A p.T388= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- ZNF479 | c.378A>G p.K126= | Silent (SNP) | VAF 57/346 reads (16%) | called by muse, mutect2
- ZNF793 | c.882G>A p.Q294= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- AC098591.2 | n.933T>G | RNA (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-4939T>A | Intron (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- AGAP7P | n.1321C>A | RNA (SNP) | VAF 93/476 reads (20%) | called by muse, mutect2, varscan2
- AMDHD1 | c.-14C>T | 5'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- AMOTL2 | chr3:134375220 C>T | 5'Flank (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- ANKRD20A8P | n.590A>G | RNA (SNP) | VAF 24/249 reads (10%) | called by muse, mutect2, varscan2
- BAGE2 | n.96C>A | RNA (SNP) | VAF 13/331 reads (4%) | catalogued as rs1186289330; called by muse, mutect2
- CFAP299 | c.242+57346T>A | Intron (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- CFAP410 | c.643-212del | Intron (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- COL1A2 | c.3106-51G>T | Intron (SNP) | VAF 37/204 reads (18%) | called by muse, mutect2, varscan2
- CSKMT | c.*440G>A | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- DNAH5 | c.7408-68T>C | Intron (SNP) | VAF 26/148 reads (18%) | catalogued as rs1348577742; called by muse, mutect2, varscan2
- EIF4A2 | c.209-82A>G | Intron (SNP) | VAF 22/122 reads (18%) | catalogued as rs765264400; called by muse, mutect2, varscan2
- ELP4 | c.1147-19962G>A | Intron (SNP) | VAF 11/50 reads (22%) | catalogued as COSV63352360; called by muse, mutect2, varscan2
- GABRB3 | c.-42_-2del | 5'UTR (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel
- LGALS3 | c.597+780C>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MATR3 | c.*1458A>G | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- MS4A6A | c.282+136G>T | Intron (SNP) | VAF 16/39 reads (41%) | catalogued as rs996768797; called by mutect2, varscan2
- NCR1 | c.70+20C>G | Intron (SNP) | VAF 11/123 reads (9%) | catalogued as rs773096323; called by muse, mutect2
- NEBL | c.*43A>G | 3'UTR (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- NPIPB1P | n.530A>G | RNA (SNP) | VAF 91/315 reads (29%) | catalogued as rs758221865; called by muse, mutect2, varscan2
- PTGES2 | chr9:128128633 G>A | 5'Flank (SNP) | VAF 25/85 reads (29%) | catalogued as rs1345887646; called by muse, mutect2, varscan2
- RAB5C | c.-88-1045C>T | Intron (SNP) | VAF 30/119 reads (25%) | called by muse, varscan2
- RIPK3 | c.665-37G>T | Intron (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.1539+14C>A | Intron (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- SMARCC1 | c.1457+43C>T | Intron (SNP) | VAF 38/105 reads (36%) | catalogued as rs367679652; called by muse, mutect2, varscan2
- SUPT5H | c.307+9G>C | Intron (SNP) | VAF 25/130 reads (19%) | catalogued as rs1436560228; called by muse, mutect2, varscan2
- ZEB2 | c.73+4001G>A | Intron (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
